Somatic mutation profile of tumor specimen TARGET-20-PASURR-09A (aliquot TARGET-20-PASURR-09A-01D) from TARGET case TARGET-20-PASURR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.2 years (4,831 days).
Specimen TARGET-20-PASURR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eda91874-f826-4bda-9399-09af069e7aab.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASURR-14A (Bone Marrow Normal), aliquot TARGET-20-PASURR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd712873-1dd2-4d2d-a275-ad726329c6cb

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/247 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as CM041493, CM920718, CM982050, COSV60065677, COSV60065800, COSV60069955; called by muse, mutect2, varscan2
- DNAH9 | c.4371C>A p.T1457= | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as rs773463222, COSV99306093; called by muse, mutect2, varscan2
